Gene-level copy-number profile of tumor specimen CDDP-ABKI-TTP1-A from CDDP_EAGLE case CDDP-ABKI, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60 years.
Specimen CDDP-ABKI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 50f5c4ab-2e9a-4135-82d4-ce7f84f35a93.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABKI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/c15b3339-192e-42e8-b3f0-050dec72d827

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 513; copy number 1: 172; copy number 2: 9,028; copy number 3: 11,702; copy number 4: 16,093; copy number 5: 10,379; copy number 6: 6,347; copy number 7: 2,959; copy number 8: 1,266; copy number 9: 149; copy number 10: 19; copy number 11: 93; copy number 12: 1; copy number 13: 49; copy number 14: 15; copy number 15: 42; copy number 16: 48; copy number 19: 22; copy number 21: 2; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:115,633,540–115,643,916, 1 gene: LINC02534.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 441 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,590,102–241,677,376, 3 genes, copy number 10 (within-gene range 8–10): OPN3, CHML, AL133390.1.
- chr2:132,147,591–154,460,820, 237 genes, copy number 9–11 (broad region; genes not listed).
- chr7:127,652,194–128,092,609, 1 gene, copy number 9 (within-gene range 5–9): SND1.
- chr7:127,997,597–128,506,602, 19 genes, copy number 9: SND1-IT1, LRRC4, MIR593, MIR129-1, LEP, AC018635.2, RBM28, AC018635.1, RNU7-27P, PRRT4, IMPDH1, AC010655.1, RNU7-54P, AC010655.4, HILPDA, AC010655.2, AC010655.3, METTL2B, Metazoa_SRP.
- chr12:18,080,869–20,370,262, 28 genes, copy number 13 (within-gene range 5–13): RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468, AC129102.1.
- chr12:37,575,587–38,589,812, 14 genes, copy number 11–15: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2.
- chr12:69,359,710–73,143,858, 55 genes, copy number 12–23: YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2.
- chr12:123,575,891–126,772,519, 84 genes, copy number 13–16 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
